Somatic mutation profile of tumor specimen TCGA-BR-8686-01A (aliquot TCGA-BR-8686-01A-11D-2394-08) from TCGA case TCGA-BR-8686, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 69.5 years (25,372 days).
Specimen TCGA-BR-8686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a0b2a75-cf38-4503-9116-91a4af8d530d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8686-10A (Blood Derived Normal), aliquot TCGA-BR-8686-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/440e4a70-314b-4dba-8cc2-292d2edcb2fc

The open-access MAF lists 110 somatic variants for this specimen: 82 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 27, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 2, Splice Region 1, Intron 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.4174C>T p.Q1392* | Nonsense Mutation (SNP) | VAF 2/15 reads (13%) | catalogued as rs886043496, CM159883; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.3796C>A p.L1266M (on ENST00000614293; = p.L1236M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV99687487; called by muse, mutect2
- ABCD4 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745414252, COSV53992169; called by muse, mutect2, varscan2
- ACAD9 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs368630371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGFG2 | c.882C>A p.S294R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.312); catalogued as COSV53544817, COSV53544996; called by muse, mutect2, varscan2
- ANKIB1 | c.2410G>A p.G804S | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs939247560, COSV56060974; called by muse, mutect2
- ANKRD30A | c.2830C>A p.H944N (on ENST00000611781; = p.H888N on NM_052997.2) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV64609349; called by muse, mutect2
- ANO4 | c.430G>T p.A144S (on ENST00000392977 / NM_001286615.2; = p.A109S on NM_178826.4) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.323); catalogued as COSV100152682; called by muse, mutect2
- ARID1A | c.2451del p.L818Cfs*15 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as COSV61392670; called by mutect2, pindel, varscan2
- ASB13 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.225); catalogued as rs761943608, COSV63090521; called by muse, mutect2, varscan2
- BRINP1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV56298649; called by muse, mutect2
- CBLL1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.424); catalogued as COSV56028816; called by muse, mutect2
- CDH1 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776975632, CM072929, COSV55728026, COSV99931786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIT | c.4454-1G>A p.X1485_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV55867433; called by muse, mutect2, varscan2
- CKAP5 | c.5043G>C p.Q1681H (on ENST00000529230 / NM_001008938.4; = p.Q1621H on NM_014756.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.459); catalogued as COSV56367294; called by muse, mutect2, varscan2
- COL4A5 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV100087433, COSV60374442; called by muse, mutect2, varscan2
- DCAF12L2 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.243); catalogued as COSV63581436; called by muse, mutect2, varscan2
- EP300 | c.5258G>T p.C1753F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99608272; called by muse, mutect2
- EVI5L | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as COSV54485434; called by muse, mutect2
- FAM135B | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs781523806, COSV52704264; called by muse, mutect2
- FOXP2 | c.1603A>C p.T535P | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63485437; called by muse, mutect2
- GNG11 | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV50350262; called by muse, mutect2, varscan2
- GRIK1 | c.479C>A p.A160E | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58716950, COSV58719779; called by muse, mutect2
- HIPK1 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as rs192499620, COSV65784410; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1621A>T p.S541C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV61155311; called by muse, mutect2, varscan2
- KCNH8 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60460560, COSV60462614; called by muse, mutect2
- KIF6 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54675849; called by muse, mutect2, varscan2
- KIR2DL4 | c.977G>T p.R326M (on ENST00000396284; = p.R252M on NM_001080770.2) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs536671464, COSV100428525; called by muse, mutect2
- KIRREL2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV52876098; called by muse, mutect2
- KNDC1 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.266); catalogued as rs1209499167, COSV100465461, COSV58836199; called by muse, mutect2, varscan2
- LRR1 | c.49T>G p.L17V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100023075; called by muse, mutect2
- LRRN3 | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1447589572, COSV57819353; called by muse, mutect2
- MPL | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs971379181, COSV65244568; called by muse, mutect2, varscan2
- MYH2 | c.5243A>G p.E1748G | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV55437177; called by muse, mutect2, varscan2
- MYH8 | c.4259C>T p.T1420M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs150344258; called by muse, mutect2, varscan2
- MYOCD | c.1953G>T p.L651F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV58502966; called by muse, mutect2, varscan2
- NCOA6 | c.4181G>A p.S1394N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV62863251; called by muse, mutect2, varscan2
- NFRKB | c.333C>A p.F111L (on ENST00000446488 / NM_001143835.2; = p.F124L on NM_006165.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.97); catalogued as COSV58757779; called by muse, varscan2
- NOTCH4 | c.5672G>C p.G1891A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV66680476; called by muse, mutect2
- NPAS2 | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs770699838, COSV59557427; called by mutect2, varscan2
- OR2A1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs750474119, COSV68822756; called by muse, mutect2
- OR2A14 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780459337, COSV68717851; called by muse, mutect2, varscan2
- OR2L8 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV61726643; called by muse, mutect2
- OR4C11 | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1024643970, COSV56353040; called by muse, mutect2, varscan2
- OR51B5 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56175885; called by muse, mutect2, varscan2
- OR5R1 | c.400A>C p.T134P | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV56572192; called by muse, mutect2, varscan2
- OR6Y1 | c.952C>A p.Q318K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100225342; called by muse, mutect2, varscan2
- PCDH15 | c.3319G>T p.V1107F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs762677779, COSV100219465; called by muse, mutect2, varscan2
- PCDH7 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV62338510; called by muse, mutect2
- PIH1D1 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV51807045; called by muse, mutect2, varscan2
- POU4F2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.06); catalogued as rs753186078, COSV55584090; called by muse, mutect2, varscan2
- PPP1R3A | c.1747C>T p.H583Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV52881576; called by muse, mutect2, varscan2
- PRAM1 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55313436; called by muse, mutect2
- PROX1 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV54778577; called by muse, mutect2
- PTPN5 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs776586245, COSV62125176; called by mutect2, varscan2
- RALGAPA1 | c.4744G>C p.G1582R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99354337; called by mutect2, varscan2
- SALL1 | c.2491G>A p.D831N | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs1475180739, COSV51756863; called by muse, mutect2, varscan2
- SBF2 | c.5520C>A p.D1840E | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.773); catalogued as COSV56298049; called by muse, mutect2
- SH3GLB1 | c.356T>G p.I119S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV65279807; called by muse, mutect2, varscan2
- SLC6A17 | c.447C>A p.V149= | Splice Region (SNP) | VAF 6/71 reads (8%) | catalogued as COSV58992880; called by muse, mutect2
- TJP1 | c.3092C>A p.P1031Q | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV62041577; called by muse, mutect2, varscan2
- TMEM132D | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1437316426, COSV70603039; called by muse, mutect2
- TOR1AIP2 | c.791A>T p.D264V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV62626033; called by muse, mutect2, varscan2
- TPH2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61591807; called by muse, mutect2
- TTC31 | c.926C>A p.A309E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52035019; called by muse, mutect2, varscan2
- TTN | c.22309C>A p.H7437N (on ENST00000591111; = p.H6510N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | PolyPhen benign (0); catalogued as COSV100607522; called by muse, mutect2, varscan2
- USH1G | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1306710776, COSV58881724; called by muse, mutect2, varscan2
- VEGFD | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52909530; called by muse, mutect2
- YPEL1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs779788033, COSV58606255, COSV58608213; called by muse, mutect2, varscan2
- ZNF33A | c.951C>G p.H317Q (on ENST00000458705 / NM_006974.3; = p.H318Q on NM_006954.2) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs758094484; called by muse, mutect2, varscan2
- ZNF420 | c.1114T>C p.F372L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58493866; called by muse, mutect2, varscan2
- ZNF549 | c.1019C>T p.S340L (on ENST00000376233 / NM_001199295.2; = p.S327L on NM_153263.2) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.35); catalogued as COSV53725038; called by muse, mutect2, varscan2
- ZNF594 | c.2157G>A p.W719* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV68385186; called by muse, mutect2, varscan2
- AKAP6 | c.6744G>T p.K2248N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); called by muse, mutect2
- DMD | c.4173G>C p.K1391N | Missense Mutation (SNP) | VAF 2/15 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2
- PFKL | c.1605dup p.D536Rfs*18 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- SRRM1 | c.1045_1047del p.X349_splice | Splice Site (DEL) | VAF 10/63 reads (16%) | called by pindel, varscan2
- TTN | c.56848G>T p.E18950* (on ENST00000591111; = p.E11526* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- WNT7B | c.409_411dup p.K137dup | In Frame Ins (INS) | VAF 5/48 reads (10%) | called by mutect2, pindel
- ZNF462 | c.2813_2831del p.R938Tfs*8 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel
- ZNF608 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2
- ARHGEF1 | c.330C>T p.L110= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs782791739, COSV61527571, COSV61528016; called by muse, mutect2
- ATOH8 | c.225G>A p.P75= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs761163650, COSV60400280; called by mutect2, varscan2
- ATR | c.1911G>A p.V637= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV63386179; called by muse, mutect2, varscan2
- CERK | c.963C>T p.S321= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV53451105; called by muse, mutect2
- CTNND2 | c.2361G>A p.T787= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs757968137, COSV58885552, COSV58902765; called by muse, varscan2
- DCAF4 | c.1455C>T p.V485= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs1424216938, COSV62319497; called by muse, mutect2, varscan2
- DMXL1 | c.2301A>G p.G767= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV60710531; called by muse, mutect2, varscan2
- DUOX1 | c.1494C>T p.S498= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV58480172; called by muse, mutect2
- ENPP7 | c.630G>A p.P210= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs146147882; called by muse, mutect2, varscan2
- EPN2 | c.1491C>T p.V497= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs755304911, COSV59061015; called by muse, mutect2, varscan2
- FBH1 | c.1347G>A p.L449= (on ENST00000362091 / NM_178150.3; = p.L500= on NM_032807.4) | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV62982421; called by muse, mutect2, varscan2
- GPR63 | c.738T>C p.I246= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV57741036; called by muse, mutect2
- GPR83 | c.75C>T p.D25= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV54718536; called by muse, mutect2, varscan2
- KRTAP19-1 | c.12C>T p.Y4= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs200649377, COSV66861170; called by muse, mutect2, varscan2
- MAGEA12 | c.570G>T p.L190= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV63294734; called by muse, mutect2, varscan2
- NEK9 | c.1497G>A p.K499= | Silent (SNP) | VAF 4/92 reads (4%) | catalogued as COSV53130857; called by muse, mutect2
- OR9G4 | c.585C>T p.Y195= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs149148369; called by muse, mutect2, varscan2
- PCDHB9 | c.2163G>A p.S721= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as rs781798964, COSV53377072; called by muse, mutect2, varscan2
- PIKFYVE | c.2904T>A p.P968= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV52240408; called by muse, mutect2, varscan2
- PLEKHG1 | c.1053G>A p.T351= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs148074221; called by muse, mutect2, varscan2
- PNMA8A | c.924G>A p.A308= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs112515812, COSV58136030; called by muse, mutect2
- SLC16A4 | c.195C>T p.I65= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV63916475; called by muse, mutect2, varscan2
- SLC39A11 | c.342G>A p.L114= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs761969127, COSV55287489; called by muse, mutect2, varscan2
- SLC52A3 | c.1356C>T p.N452= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs773933101, COSV54077302; called by muse, mutect2
- TSNARE1 | c.483C>T p.Y161= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV56175125; called by mutect2, varscan2
- TYMP | c.387C>T p.L129= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs773716239, COSV52686687; called by muse, mutect2, varscan2
- ZNF780A | c.129C>A p.I43= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs1389673388, COSV100575060; called by muse, mutect2
- PDGFD | c.125-36714G>A | Intron (SNP) | VAF 30/81 reads (37%) | catalogued as rs764000612, COSV56376730; called by muse, mutect2, varscan2
